Somatic mutation profile of tumor specimen HTMCP-03-06-02339-01A (aliquot HTMCP-03-06-02339-01A-01D-9392) from CGCI case HTMCP-03-06-02339, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G4.
Specimen HTMCP-03-06-02339-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1ca9ed9-8fa9-4748-a9a6-5c550c8730c7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02339-10A (Blood Derived Normal), aliquot HTMCP-03-06-02339-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11877f8f-6543-4723-9baa-428de225b8ef

The open-access MAF lists 505 somatic variants for this specimen: 372 protein-altering or splice-affecting, 106 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 106, Nonsense Mutation 28, Splice Site 12, Intron 10, RNA 8, Splice Region 5, 3'UTR 5, 5'Flank 2, In Frame Del 2, 5'UTR 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.6241C>T p.Q2081* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs886041518, COSV99268863; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs28381902; called by muse, mutect2, varscan2
- ADAM17 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60397370; called by muse, mutect2, varscan2
- ADAMTS1 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1451629973; called by muse, mutect2, varscan2
- ADAMTS8 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs772968405; called by muse, mutect2, varscan2
- AHNAK2 | c.15388G>A p.E5130K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.018); catalogued as rs776069775; called by muse, mutect2, varscan2
- AHNAK2 | c.7944C>G p.F2648L | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.099); catalogued as COSV60922093; called by muse, mutect2, varscan2
- ALOX5 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65553372; called by muse, mutect2, varscan2
- ANO3 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99881109; called by muse, mutect2, varscan2
- ARHGEF10L | c.3799G>A p.D1267N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); catalogued as COSV51431809; called by muse, mutect2
- ARHGEF15 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); catalogued as COSV62725910; called by muse, mutect2, varscan2
- ARHGEF6 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs767903935, COSV51695174; called by muse, mutect2, varscan2
- ARID4A | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62164947, COSV62165196; called by muse, mutect2, varscan2
- ASH1L | c.6721C>T p.R2241W (on ENST00000368346 / NM_001366177.2; = p.R2236W on NM_018489.3) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64205647; called by muse, mutect2, varscan2
- ATP10B | c.2838+3G>A | Splice Region (SNP) | VAF 13/42 reads (31%) | catalogued as rs369524873; called by muse, mutect2, varscan2
- ATRX | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV64885777; called by muse, mutect2, varscan2
- BAZ2A | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as rs1307986373; called by muse, mutect2, varscan2
- BCR | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs929189498; called by muse, mutect2
- BOC | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs773561274; called by muse, mutect2, varscan2
- CACNA1S | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs529038948; called by muse, mutect2, varscan2
- CASP8 | c.319C>T p.Q107* (on ENST00000432109 / NM_033355.3; = p.Q139* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV51851441; called by muse, mutect2, varscan2
- CCT5 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs1338375786; called by muse, mutect2, varscan2
- CD93 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs369282897, COSV99849559; called by muse, mutect2, varscan2
- CENPF | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565451023, COSV65273347; called by muse, mutect2, varscan2
- CEP152 | c.4061C>G p.S1354C (on ENST00000380950 / NM_001194998.2; = p.S1298C on NM_014985.4) | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs531199866, COSV100358660; called by muse, mutect2, varscan2
- CLIP1 | c.2822C>T p.S941F (on ENST00000620786 / NM_001247997.1; = p.S930F on NM_002956.2) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs758543229; called by muse, mutect2, varscan2
- CSMD3 | c.9274G>A p.E3092K (on ENST00000297405 / NM_001363185.1; = p.E2923K on NM_052900.3) | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.253); catalogued as rs187483049; called by muse, mutect2, varscan2
- CTNNBL1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs746340982; called by muse, mutect2, varscan2
- CUL7 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1338104839; called by muse, mutect2, varscan2
- DDX27 | c.1781-3G>A | Splice Region (SNP) | VAF 32/187 reads (17%) | catalogued as COSV65609288; called by muse, mutect2, varscan2
- DDX60 | c.4429C>G p.Q1477E | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs751155591, COSV101190516, COSV67096420; called by muse, mutect2, varscan2
- DHX33 | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755965533, COSV56580973; called by muse, mutect2, varscan2
- DNAH1 | c.8005C>A p.L2669M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as rs773366648; called by muse, mutect2, varscan2
- ENTHD1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 70/188 reads (37%) | catalogued as rs557485962; called by muse, mutect2, varscan2
- EP300 | c.2855C>G p.S952* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as COSV54329736, COSV99608957; called by muse, mutect2, varscan2
- EYS | c.5588C>A p.S1863Y | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV58196009; called by muse, mutect2, varscan2
- FANCA | c.3877G>A p.E1293K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs1015729981, COSV57067891; called by muse, mutect2, varscan2
- FCRL4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV54860901, COSV54862331; called by muse, mutect2, varscan2
- FILIP1L | c.2254C>G p.Q752E (on ENST00000354552 / NM_182909.3; = p.Q512E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/270 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.152); catalogued as COSV100496419; called by muse, mutect2, varscan2
- FNDC1 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51950403; called by muse, mutect2, varscan2
- FSIP2 | c.17989G>C p.E5997Q | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs773605266, COSV58080005; called by muse, mutect2, varscan2
- GATA3 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV60516456; called by muse, mutect2, varscan2
- GSN | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs372681751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUCY2D | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV54696778; called by muse, mutect2, varscan2
- HCN1 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as COSV57523526; called by muse, mutect2, varscan2
- HERC2 | c.14224G>A p.V4742I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs778253807, COSV55332273; called by muse, mutect2, varscan2
- HTATSF1 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99511426; called by muse, mutect2, varscan2
- HUWE1 | c.8342G>C p.G2781A | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV53366296; called by muse, mutect2, varscan2
- HUWE1 | c.4111G>C p.E1371Q | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV53350286; called by muse, mutect2, varscan2
- IPO4 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1261600365; called by muse, mutect2
- IPO7 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776773651; called by muse, mutect2, varscan2
- ITGA4 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV99276876; called by muse, mutect2, varscan2
- ITPR1 | c.2404G>A p.V802M (on ENST00000354582; = p.V787M on NM_002222.7) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs369080877; called by muse, mutect2, varscan2
- ITSN1 | c.4189C>G p.P1397A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV67157273; called by muse, mutect2, varscan2
- KALRN | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs765575292, COSV53782687; called by muse, mutect2, varscan2
- KAT6B | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs545973592, COSV99768640; called by muse, mutect2, varscan2
- KIAA1210 | c.4969C>T p.Q1657* | Nonsense Mutation (SNP) | VAF 35/145 reads (24%) | catalogued as COSV68179718; called by muse, mutect2, varscan2
- KIF13A | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV52457795; called by muse, mutect2, varscan2
- KIF20B | c.2411C>T p.S804F (on ENST00000371728 / NM_001284259.2; = p.S764F on NM_016195.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV53304726; called by muse, mutect2, varscan2
- LAMA3 | c.5654G>A p.G1885E (on ENST00000313654 / NM_198129.4; = p.G276E on NM_000227.6) | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.187); catalogued as COSV52544909; called by muse, mutect2, varscan2
- LGALS3BP | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs776549166, COSV53164511, COSV53164591; called by muse, mutect2, varscan2
- LRP1 | c.11762C>T p.T3921M | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.948); catalogued as rs530977436; called by muse, mutect2, varscan2
- LRP1B | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs762893880; called by muse, mutect2, varscan2
- LRP2 | c.8442G>T p.E2814D | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1353621100, COSV55548655; called by muse, mutect2, varscan2
- MACF1 | c.2413C>A p.L805I | Missense Mutation (SNP) | VAF 38/103 reads (37%) | catalogued as COSV58367412; called by muse, mutect2, varscan2
- MAGEB6 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV66873527; called by muse, mutect2, varscan2
- MAGEC1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV53568020, COSV53576550; called by muse, mutect2, varscan2
- MAGEC3 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV100024804, COSV71610092; called by muse, mutect2, varscan2
- MAGED2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs199838183; called by muse, mutect2, varscan2
- MAMLD1 | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV53374821; called by muse, mutect2, varscan2
- MAP4K1 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67711165; called by muse, mutect2, varscan2
- MAP7 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63418932; called by muse, mutect2, varscan2
- MCF2 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs868555611; called by muse, mutect2, varscan2
- MDN1 | c.4649G>A p.S1550N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV65530067; called by muse, mutect2, varscan2
- MECOM | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs760911163; called by muse, mutect2, varscan2
- MED1 | c.2947C>T p.L983F | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.033); catalogued as rs922873446; called by muse, mutect2, varscan2
- MED1 | c.2125C>A p.Q709K | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100327499; called by muse, mutect2, varscan2
- MED14 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100247390; called by muse, mutect2, varscan2
- MGA | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV54950617; called by muse, mutect2, varscan2
- MGA | c.8221G>A p.E2741K (on ENST00000219905 / NM_001164273.1; = p.E2532K on NM_001080541.2) | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV54963070; called by muse, mutect2, varscan2
- MLPH | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV52819728; called by muse, mutect2, varscan2
- MMS22L | c.3188C>T p.S1063L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1234266619; called by muse, mutect2, varscan2
- MUC17 | c.10774G>A p.E3592K | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as rs748163643; called by muse, mutect2, varscan2
- MUC19 | c.163-3C>T | Splice Region (SNP) | VAF 21/61 reads (34%) | catalogued as COSV70102137; called by muse, mutect2, varscan2
- MUC4 | c.7415C>T p.S2472L | Missense Mutation (SNP) | VAF 57/544 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.316); catalogued as rs1227451227, COSV100641515; called by muse, mutect2, varscan2
- MUC5B | c.4886C>T p.S1629L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV71596135; called by muse, mutect2, varscan2
- MXRA5 | c.4156G>C p.A1386P | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV99477437; called by muse, mutect2, varscan2
- MYH2 | c.2797G>C p.E933Q | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV55447111; called by muse, mutect2, varscan2
- MYH3 | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780780930; called by muse, mutect2, varscan2
- MYH9 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53384901; called by muse, mutect2, varscan2
- MYO10 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1228416361; called by muse, mutect2, varscan2
- NDUFB11 | c.408C>G p.I136M (on ENST00000377811 / NM_001135998.3; = p.I146M on NM_019056.6) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs782327477; called by muse, mutect2, varscan2
- NEB | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV50805982; called by muse, mutect2, varscan2
- NIPBL | c.5209C>G p.Q1737E | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.066); catalogued as COSV56972288; called by muse, mutect2, varscan2
- NSD1 | c.7067C>A p.T2356K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs780750393, COSV61775750; called by muse, mutect2, varscan2
- NYNRIN | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV66841045; called by muse, mutect2, varscan2
- PABPC3 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as rs781743930; called by muse, mutect2, varscan2
- PCDHB16 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs373129199; called by muse, mutect2, varscan2
- PCSK5 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs373133250; called by muse, mutect2, varscan2
- PDE4D | c.835G>A p.E279K (on ENST00000340635 / NM_001104631.2; = p.E143K on NM_006203.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs1455341183, COSV58938445; called by muse, mutect2, varscan2
- PDS5A | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57833105; called by muse, mutect2, varscan2
- PKD1L1 | c.5861C>T p.T1954M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs766982650, COSV56961409; called by muse, mutect2, varscan2
- PLEC | c.1325G>A p.R442H (on ENST00000322810 / NM_201380.4; = p.R332H on NM_000445.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1003535743, COSV59647073; called by muse, mutect2
- PLEKHH3 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV53188421; called by muse, mutect2, varscan2
- PLXNA3 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs782378456; called by muse, mutect2, varscan2
- PPFIA2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779142085, COSV100331902, COSV61043239; called by muse, mutect2, varscan2
- PREX2 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV55779029; called by muse, mutect2, varscan2
- PRG4 | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs1476098760; called by muse, mutect2, varscan2
- PRKCI | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99041683; called by muse, mutect2, varscan2
- PTCH1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV59467099; called by muse, mutect2, varscan2
- PTK2B | c.2505G>A p.M835I | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV57761928; called by muse, mutect2, varscan2
- PTPRD | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV61953530; called by muse, mutect2, varscan2
- RB1 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as CM040265, COSV57314725, COSV57323773; called by muse, varscan2
- ROBO2 | c.3535G>A p.D1179N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV59943283; called by muse, mutect2, varscan2
- RTL1 | c.4048G>A p.D1350N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1453269575; called by muse, mutect2, varscan2
- RTN2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs375715266, COSV99838828; called by muse, mutect2, varscan2
- RUNX1T1 | c.689C>T p.S230L (on ENST00000265814 / NM_001198628.1; = p.S203L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV56147402; called by muse, mutect2, varscan2
- SAGE1 | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 121/295 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.329); catalogued as COSV61012521; called by muse, mutect2, varscan2
- SCN9A | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57600042; called by muse, mutect2, varscan2
- SDCCAG8 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59404991; called by muse, mutect2, varscan2
- SEMA6A | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56709111; called by muse, mutect2, varscan2
- SETD1B | c.5337G>C p.Q1779H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99930425; called by mutect2, varscan2
- SLC9C1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs143974577; called by muse, mutect2, varscan2
- SLFN11 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1049928797; called by muse, mutect2, varscan2
- SLITRK6 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV101233204; called by muse, mutect2, varscan2
- SMARCC2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as COSV57214797, COSV99911694; called by muse, mutect2, varscan2
- SMC4 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV59086721; called by muse, mutect2, varscan2
- SPHKAP | c.307-1G>A p.X103_splice | Splice Site (SNP) | VAF 68/102 reads (67%) | catalogued as COSV100763561; called by muse, mutect2, varscan2
- SPINK5 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774534780; called by muse, mutect2, varscan2
- STARD9 | c.3821C>T p.S1274L | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV51915320; called by muse, mutect2, varscan2
- STON2 | c.2485G>C p.E829Q (on ENST00000649389 / NM_001366849.2; = p.E772Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99964523; called by muse, mutect2, varscan2
- SVIL | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1276521760; called by muse, mutect2, varscan2
- SYNE1 | c.590G>A p.G197E (on ENST00000367255 / NM_182961.4; = p.G204E on NM_033071.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs150249753; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANK | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52046406; called by muse, mutect2, varscan2
- TAS1R3 | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as COSV59562624; called by muse, mutect2, varscan2
- TAS1R3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as rs764577379; called by muse, mutect2, varscan2
- TBL1XR1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV101467821, COSV70499453; called by muse, mutect2, varscan2
- TCP11L2 | c.633G>A p.L211= | Splice Region (SNP) | VAF 17/80 reads (21%) | catalogued as rs777479623; called by muse, mutect2, varscan2
- TEP1 | c.3605C>T p.S1202F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs1217332747; called by muse, mutect2, varscan2
- TKTL1 | c.1704G>C p.Q568H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1175446850; called by muse, mutect2, varscan2
- TPP2 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV65753377; called by muse, mutect2, varscan2
- TPR | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99055068; called by muse, mutect2, varscan2
- TRPA1 | c.2869-1G>A p.X957_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | catalogued as COSV100084952; called by muse, mutect2, varscan2
- TTC21A | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377643806; called by muse, mutect2, varscan2
- UNC80 | c.7184G>A p.R2395Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs1486945350; called by muse, mutect2, varscan2
- VSIG10L | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as rs534783396; called by muse, mutect2, varscan2
- WDR31 | c.310C>T p.H104Y (on ENST00000374193 / NM_001006615.3; = p.H103Y on NM_145241.5) | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs757008372; called by muse, mutect2, varscan2
- WDR87 | c.4972T>G p.L1658V | Missense Mutation (SNP) | VAF 81/217 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV100382792; called by muse, mutect2, varscan2
- ZBTB22 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV56466868, COSV56470411; called by muse, mutect2, varscan2
- ZEB1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.053); catalogued as COSV100313823; called by muse, mutect2, varscan2
- ZNF440 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.954); catalogued as COSV100407600; called by muse, mutect2, varscan2
- ZNF536 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755711056, COSV62824835; called by muse, mutect2, varscan2
- ABCA7 | c.3562G>C p.E1188Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCB1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC3 | c.3823G>A p.E1275K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ABCC5 | c.1565C>G p.A522G | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.2861T>A p.L954H | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACE | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADAM10 | c.1556C>G p.S519* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.3700C>T p.L1234F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ADGRG2 | c.2783C>T p.S928L (on ENST00000379869 / NM_001079858.3; = p.S925L on NM_005756.4) | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRL3 | c.3382C>G p.L1128V (on ENST00000506720 / NM_001322402.2; = p.L1060V on NM_015236.6) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- AKAP12 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AL592490.1 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANK2 | c.5800G>C p.E1934Q | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD36 | c.2501C>G p.S834C | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP23 | c.2580G>C p.Q860H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ARHGAP26 | c.2350G>C p.D784H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ATP2B3 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B3 | c.2667G>C p.L889F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP2B4 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BCORL1 | c.4250C>T p.S1417L | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC6 | c.11177C>T p.S3726F | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- BNC2 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
- BRD7 | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- BRWD3 | c.4546G>A p.D1516N | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- C6orf132 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CATSPERE | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 109/382 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC159 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCDC160 | c.944G>T p.S315I | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CCNB3 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC42BPG | c.2516G>C p.G839A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDC42BPG | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CELSR3 | c.4286G>A p.G1429E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP128 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CEP250 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CEP350 | c.3872A>C p.K1291T | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP85 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, varscan2
- CEP85 | c.1868C>G p.S623* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | called by muse, varscan2
- CFAP57 | c.3010-1G>A p.X1004_splice (on ENST00000372492 / NM_001378189.1; = p.X1037_splice on NM_001195831.3) | Splice Site (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- CHD9 | c.1710G>A p.M570I | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCNKA | c.1757-1G>A p.X586_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- CLEC11A | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLSTN1 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLTCL1 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CMYA5 | c.7822G>C p.E2608Q | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- COL9A1 | c.911dup p.P306Sfs*4 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- CPSF1 | c.3568-1G>A p.X1190_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- CSE1L | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CTNND2 | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 74/154 reads (48%) | called by muse, mutect2, varscan2
- CUL1 | c.1293G>C p.K431N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCLRE1A | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- DNAH17 | c.7678G>T p.D2560Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- DOCK7 | c.3772G>A p.D1258N (on ENST00000635253 / NM_001367561.1; = p.D1227N on NM_033407.3) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DSP | c.6410C>T p.P2137L | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.10318C>G p.L3440V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EGFLAM | c.2862G>A p.M954I (on ENST00000354891 / NM_001205301.2; = p.M946I on NM_152403.4) | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELF3 | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EPHA1 | c.2865G>C p.Q955H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- EPS8 | c.1337G>C p.G446A | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- EVI5 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM120C | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71E2 | c.2577G>C p.R859S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FANCD2 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- FHOD1 | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GABRG3 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GALNT14 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCKR | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- GNE | c.1948G>C p.D650H (on ENST00000396594 / NM_001128227.3; = p.D619H on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GOLGA6L10 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GPATCH1 | c.2473G>C p.D825H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- GPR158 | c.3004G>A p.D1002N | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GREB1 | c.158-1G>A p.X53_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- GRIA3 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GRIP1 | c.2677C>G p.Q893E (on ENST00000359742 / NM_001379345.1; = p.Q841E on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- GRIP1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HADHA | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- HCN1 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- HERC1 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- HMMR | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- HOXC11 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSP90AA1 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IPO4 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ITPR1 | c.8167-1G>A p.X2723_splice (on ENST00000354582; = p.X2668_splice on NM_002222.7) | Splice Site (SNP) | VAF 32/105 reads (30%) | called by muse, mutect2, varscan2
- KCNF1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- KDM2A | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM5C | c.4440G>C p.K1480N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIAA1217 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KIF26B | c.1164A>G p.A388= | Splice Region (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- KLHDC4 | c.987C>A p.F329L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KLHL4 | c.1817G>C p.R606T | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- KMT2C | c.6477C>G p.Y2159* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | called by muse, mutect2, varscan2
- KMT2C | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- KNL1 | c.2050C>T p.Q684* (on ENST00000346991 / NM_170589.5; = p.Q658* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- LIMK1 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRP1B | c.11377G>A p.E3793K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.9793C>T p.H3265Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC24 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRD1 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRIQ1 | c.2039G>A p.R680K | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRK1 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- LRRK2 | c.3811A>G p.T1271A | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MAGEC3 | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MALRD1 | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K12 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MAPK6 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MB21D2 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MED1 | c.3231_3275del p.S1078_S1092del | In Frame Del (DEL) | VAF 32/144 reads (22%) | called by mutect2, pindel
- MGAM | c.3865T>G p.F1289V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIA3 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MTA1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- MTMR1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MUC16 | c.32617G>A p.E10873K | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYEF2 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYH15 | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MYH9 | c.4627G>C p.E1543Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1L | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NBPF9 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- NCAM2 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEK4 | c.1799C>A p.S600* | Nonsense Mutation (SNP) | VAF 49/169 reads (29%) | called by muse, mutect2, varscan2
- NF1 | c.6811C>G p.L2271V (on ENST00000358273 / NM_001042492.3; = p.L2250V on NM_000267.3) | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- NLRC5 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NOL8 | c.3370C>T p.Q1124* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- NRP1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OTOF | c.5993G>C p.*1998Sext*66 (on ENST00000272371 / NM_194248.3; = p.*1231Sext*66 on NM_004802.4) | Nonstop Mutation (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- PCDH11X | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH18 | c.2320C>T p.H774Y | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PCDHB15 | c.1491C>A p.H497Q | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHGA10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCLO | c.7123C>T p.Q2375* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- PDE8A | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- PDZD7 | c.2604G>A p.M868I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- PDZD7 | c.1416C>G p.F472L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, varscan2
- PERM1 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGR | c.495G>C p.M165I | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PLCB2 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PLCG1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- POLA1 | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- POLK | c.1512G>C p.L504F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- POTEC | c.885dup p.A296Sfs*2 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.2925+1G>A p.X975_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- PPM1B | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- PRDM1 | c.601T>G p.C201G | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PROM1 | c.2077-1G>C p.X693_splice | Splice Site (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- PRR14L | c.3304G>T p.D1102Y | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PRRC2B | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PRUNE2 | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRUNE2 | c.2781G>C p.K927N | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PTPRD | c.542-1G>A p.X181_splice | Splice Site (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- RALGAPA1 | c.4936G>C p.E1646Q | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- RAPGEF2 | c.4192G>A p.E1398K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- RB1 | c.2248G>A p.D750N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, varscan2
- RBL2 | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- RGPD3 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- RIPOR2 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ROBO3 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- RSPH3 | c.1134G>C p.K378N (on ENST00000252655; = p.K236N on NM_031924.8) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RTEL1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- RTEL1 | c.3490C>T p.P1164S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTN2 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- SBF2 | c.1398G>C p.E466D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN10A | c.4458C>G p.I1486M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCUBE1 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEC16A | c.1402C>G p.Q468E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEPTIN6 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SETD2 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SF3B2 | c.2520G>A p.M840I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SI | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC11 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | called by mutect2, varscan2
- SLC17A6 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC39A4 | c.615C>A p.F205L (on ENST00000301305 / NM_001374839.1; = p.F180L on NM_017767.3) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- SLC39A7 | c.941-1G>A p.X314_splice | Splice Site (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- SLC4A3 | c.3533C>T p.S1178L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLFN11 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCA1 | c.2482C>G p.Q828E | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- SMC1A | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SPANXD | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SPTAN1 | c.6521_6531del p.A2174Dfs*69 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- SRRM5 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SUPV3L1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SYNPO2 | c.2701C>G p.Q901E | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TAF1L | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TAF1L | c.1622C>G p.S541C | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- TEP1 | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 44/156 reads (28%) | called by muse, mutect2, varscan2
- TLN2 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR7 | c.2889G>C p.K963N | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- TMLHE | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- TMTC1 | c.1383_1384del p.N462* (on ENST00000539277 / NM_001193451.2; = p.N354* on NM_175861.3) | Frame Shift Del (DEL) | VAF 54/176 reads (31%) | called by mutect2, pindel, varscan2
- TNS1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM5 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- TRIM5 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TROAP | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TTLL13P | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TTLL8 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.68129G>C p.G22710A (on ENST00000591111; = p.G15286A on NM_003319.4) | Missense Mutation (SNP) | VAF 65/177 reads (37%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBFD1 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- UBR2 | c.2006G>C p.R669T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR2 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | called by muse, varscan2
- UHRF2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ULK2 | c.59T>G p.F20C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UPF3B | c.625-1G>C p.X209_splice | Splice Site (SNP) | VAF 27/175 reads (15%) | called by muse, mutect2, varscan2
- UPF3B | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- VCPIP1 | c.1903C>G p.P635A | Missense Mutation (SNP) | VAF 153/305 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VPS13B | c.10623C>G p.I3541M | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- WRN | c.3311C>T p.S1104F | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WTAP | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- XKR6 | c.1064G>A p.R355K | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- YEATS2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZBTB22 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZEB1 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZFYVE9 | c.1696_1701del p.V566_A567del | In Frame Del (DEL) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.3682G>C p.G1228R | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF160 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF397 | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZNF462 | c.6589G>A p.E2197K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ZNF483 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF646 | c.2045G>A p.S682N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF655 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF708 | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF711 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF827 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ABL2 | c.603G>A p.E201= (on ENST00000502732 / NM_007314.4; = p.E186= on NM_005158.5) | Silent (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- ACACA | c.3729C>T p.L1243= | Silent (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- ACACB | c.3666C>A p.L1222= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- ACSM2B | c.720C>G p.L240= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- ADCY6 | c.3129G>A p.L1043= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs971716335; called by muse, mutect2, varscan2
- ANK2 | c.108C>G p.L36= | Silent (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- ASPM | c.339C>G p.L113= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV54134292; called by muse, mutect2, varscan2
- ATP2B4 | c.162C>G p.L54= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV58173846; called by muse, mutect2, varscan2
- BRD4 | c.24G>A p.G8= | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- CACNA1D | c.504C>T p.F168= | Silent (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- CAPN12 | c.1041C>T p.P347= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- CD1E | c.24C>T p.F8= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs376989417, COSV63772615; called by mutect2, varscan2
- CEP164 | c.3429C>T p.A1143= | Silent (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- CEP295 | c.7779G>A p.E2593= | Silent (SNP) | VAF 41/104 reads (39%) | called by muse, mutect2, varscan2
- CLIP1 | c.3822G>A p.Q1274= (on ENST00000620786 / NM_001247997.1; = p.Q1263= on NM_002956.2) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV56797670; called by muse, mutect2, varscan2
- CMYA5 | c.3321C>G p.L1107= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV71407126; called by muse, mutect2, varscan2
- COL5A3 | c.2214C>T p.F738= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- CPSF1 | c.3504G>A p.Q1168= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs1554862944; called by muse, mutect2, varscan2
- DNAH17 | c.9972G>A p.A3324= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as rs1198992662, COSV67749829; called by muse, mutect2, varscan2
- DNAH2 | c.12276C>G p.L4092= | Silent (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- DNM1 | c.390G>A p.L130= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- DOCK11 | c.1134C>T p.I378= | Silent (SNP) | VAF 37/226 reads (16%) | catalogued as COSV99354928; called by muse, mutect2, varscan2
- DSCAM | c.777G>A p.L259= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1159045160; called by muse, mutect2, varscan2
- DSG1 | c.1029G>A p.Q343= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs1338061806; called by muse, mutect2, varscan2
- EIF4G1 | c.4665G>A p.V1555= (on ENST00000346169 / NM_198241.3; = p.V1360= on NM_004953.5) | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- EPHA1 | c.360G>A p.E120= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- FBN3 | c.5943C>G p.L1981= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- FLNC | c.3807G>C p.V1269= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV57954502; called by muse, mutect2
- FLRT2 | c.99C>G p.L33= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as COSV58150120; called by muse, mutect2, varscan2
- GJC1 | c.429G>A p.E143= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as COSV57910727; called by muse, mutect2, varscan2
- GPI | c.474C>T p.G158= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs772183365; called by muse, mutect2, varscan2
- GRIP1 | c.1425G>A p.L475= (on ENST00000359742 / NM_001379345.1; = p.L423= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV54029336; called by muse, mutect2, varscan2
- HDAC11 | c.819C>T p.I273= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- HYDIN | c.14532C>G p.V4844= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- IQSEC1 | c.1971C>T p.F657= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs187069097; called by muse, mutect2, varscan2
- ITPRID1 | c.2943G>A p.P981= | Silent (SNP) | VAF 92/203 reads (45%) | catalogued as rs145933301; called by muse, mutect2, varscan2
- ITSN1 | c.4362G>A p.V1454= | Silent (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- JMJD1C | c.270C>T p.A90= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs1452187493; called by muse, varscan2
- JMY | c.2848C>T p.L950= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as COSV101268062; called by muse, mutect2, varscan2
- KIF13A | c.4149C>T p.L1383= | Silent (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- LAMC1 | c.4596G>A p.L1532= | Silent (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- MBD5 | c.3474G>A p.L1158= | Silent (SNP) | VAF 63/166 reads (38%) | catalogued as rs771093661; called by muse, mutect2, varscan2
- MORC4 | c.1188C>T p.L396= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV55245795; called by muse, mutect2, varscan2
- MYH11 | c.3990G>A p.Q1330= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- MYOF | c.6135C>T p.L2045= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs377176578; called by muse, mutect2, varscan2
- MYOM3 | c.3123C>T p.F1041= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- NAALADL2 | c.2370C>T p.V790= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV71984566, COSV71984593; called by muse, mutect2, varscan2
- NBN | c.1866G>A p.K622= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- NIN | c.5943C>T p.L1981= (on ENST00000382041 / NM_182946.1; = p.L1268= on NM_016350.4) | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- NIPBL | c.6807T>C p.D2269= | Silent (SNP) | VAF 48/207 reads (23%) | catalogued as rs746375194; called by muse, mutect2, varscan2
- NKAPD1 | c.174G>A p.R58= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV54777799; called by muse, mutect2, varscan2
- NLRP6 | c.1653G>A p.L551= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- NOS3 | c.1266C>T p.A422= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs534664057, COSV52496708; ClinVar: likely benign; called by mutect2, varscan2
- NPAS4 | c.978G>A p.L326= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV60652144; called by muse, mutect2, varscan2
- OGA | c.1863G>A p.V621= | Silent (SNP) | VAF 56/138 reads (41%) | called by muse, mutect2, varscan2
- OR2W3 | c.117C>G p.L39= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV64456256; called by muse, mutect2, varscan2
- OTOF | c.5568G>A p.R1856= (on ENST00000272371 / NM_194248.3; = p.R1089= on NM_004802.4) | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- OTOP1 | c.1239C>A p.L413= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- PCDH9 | c.2352C>T p.I784= | Silent (SNP) | VAF 55/175 reads (31%) | catalogued as rs1401031210, COSV100123452, COSV60594219; called by muse, mutect2, varscan2
- PCDHB4 | c.1710C>T p.P570= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- PCIF1 | c.612C>G p.L204= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV65026656; called by muse, mutect2, varscan2
- PFKFB1 | c.723C>G p.V241= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV66627998; called by muse, mutect2, varscan2
- PGK1 | c.1242C>T p.L414= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as rs781803907, COSV59370696; called by muse, mutect2, varscan2
- PHLPP1 | c.1686C>T p.V562= | Silent (SNP) | VAF 53/165 reads (32%) | catalogued as rs181263570; called by muse, mutect2, varscan2
- PIEZO1 | c.564C>T p.F188= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PLCL2 | c.1294C>T p.L432= (on ENST00000615277 / NM_001144382.2; = p.L306= on NM_015184.5) | Silent (SNP) | VAF 65/223 reads (29%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.4140C>T p.L1380= | Silent (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- PQBP1 | c.276C>G p.L92= | Silent (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- PRDM16 | c.1200C>T p.H400= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99577633; called by muse, mutect2, varscan2
- PRG4 | c.3327C>T p.L1109= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as rs751539819; called by muse, mutect2, varscan2
- PRPF6 | c.1359G>A p.L453= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV53867984; called by muse, mutect2, varscan2
- PTGFRN | c.2136C>T p.I712= | Silent (SNP) | VAF 72/200 reads (36%) | catalogued as rs769186484; called by muse, mutect2, varscan2
- RANBP2 | c.9450G>C p.V3150= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- RGPD3 | c.4770G>A p.Q1590= | Silent (SNP) | VAF 49/393 reads (12%) | called by muse, mutect2, varscan2
- RNF40 | c.2112G>A p.R704= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- SATB1 | c.2229G>A p.V743= | Silent (SNP) | VAF 106/206 reads (51%) | called by muse, mutect2, varscan2
- SEMA4B | c.2442C>T p.F814= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs369425943; called by muse, mutect2, varscan2
- SEMA6A | c.993C>T p.D331= | Silent (SNP) | VAF 52/138 reads (38%) | called by muse, mutect2, varscan2
- SKOR2 | c.3036C>T p.L1012= | Silent (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2, varscan2
- SLC26A8 | c.1188C>T p.I396= | Silent (SNP) | VAF 38/143 reads (27%) | called by muse, varscan2
- SLC8A2 | c.585G>C p.L195= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV52639324; called by muse, mutect2, varscan2
- SMARCAD1 | c.1860G>A p.L620= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs1251634879; called by muse, mutect2, varscan2
- SNRNP200 | c.936C>T p.F312= | Silent (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- SORL1 | c.5544C>T p.L1848= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs1459177625; called by muse, mutect2, varscan2
- SPTA1 | c.4677C>T p.I1559= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV63751319, COSV63752708; called by muse, mutect2, varscan2
- SRCAP | c.2319G>A p.L773= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as rs748568329, COSV52673430; called by muse, mutect2, varscan2
- SRCIN1 | c.2181G>A p.L727= (on ENST00000621492; = p.L693= on NM_025248.3) | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- SUN2 | c.1479C>G p.L493= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- SUPT5H | c.3012C>T p.I1004= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- TIGD6 | c.1281C>G p.L427= | Silent (SNP) | VAF 77/235 reads (33%) | called by muse, mutect2, varscan2
- TONSL | c.471G>C p.L157= | Silent (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- TOX | c.759G>A p.K253= | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as COSV63847423; called by muse, mutect2, varscan2
- TPSD1 | c.210C>G p.L70= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, varscan2
- TRIP12 | c.2313C>T p.L771= | Silent (SNP) | VAF 41/124 reads (33%) | called by muse, mutect2, varscan2
- TTBK1 | c.1272G>A p.Q424= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs775850715; called by muse, mutect2, varscan2
- TTN | c.4731C>T p.V1577= (on ENST00000591111; = p.V1531= on NM_003319.4) | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- ULK2 | c.60C>T p.F20= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs779449876; called by mutect2, varscan2
- ULK4 | c.354C>G p.L118= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV57215315; called by muse, mutect2, varscan2
- VPS13B | c.798C>T p.I266= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- VPS13B | c.6640C>T p.L2214= | Silent (SNP) | VAF 70/145 reads (48%) | catalogued as COSV100661965; called by muse, mutect2, varscan2
- VWDE | c.1684C>T p.L562= | Silent (SNP) | VAF 30/120 reads (25%) | called by muse, mutect2, varscan2
- XKR4 | c.54G>A p.A18= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs376971701; called by mutect2, varscan2
- ZC3H18 | c.2310G>A p.R770= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV104396080, COSV56325593; called by muse, mutect2, varscan2
- ZEB2 | c.1926G>A p.E642= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as COSV104410544, COSV57957076; called by muse, mutect2, varscan2
- ZNF236 | c.2139C>T p.F713= | Silent (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- ZNF546 | c.138G>A p.L46= | Silent (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- AC093787.2 | n.491T>C | RNA (SNP) | VAF 35/142 reads (25%) | catalogued as rs1406506101; called by muse, varscan2
- AC137761.1 | n.470G>T | RNA (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- ANKRD20A7P | n.95C>T | RNA (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- CDC27P1 | n.128G>C | RNA (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- CR383658.1 | n.169G>C | RNA (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- DNAH14 | c.7717-146T>A | Intron (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- ECE2 | c.401-30C>G | Intron (SNP) | VAF 48/233 reads (21%) | called by muse, mutect2, varscan2
- EML2 | chr19:45641671 G>C | 5'Flank (SNP) | VAF 7/24 reads (29%) | catalogued as rs760708376; called by muse, mutect2, varscan2
- FAM120A | c.1734+96C>G | Intron (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- FAM131A | c.*585C>T | 3'UTR (SNP) | VAF 22/108 reads (20%) | catalogued as rs1239772408; called by muse, mutect2, varscan2
- GCNT2 | c.926-35006T>G | Intron (SNP) | VAF 100/200 reads (50%) | called by muse, mutect2, varscan2
- IGSF22 | c.2696-212C>T | Intron (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- IRAK1 | c.*833G>A | 3'UTR (SNP) | VAF 34/158 reads (22%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2266+5804C>G | Intron (SNP) | VAF 26/68 reads (38%) | catalogued as rs1313905624; called by muse, mutect2, varscan2
- KPNA7 | c.-1T>C | 5'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- LINC01410 | n.1869G>A | RNA (SNP) | VAF 44/704 reads (6%) | called by muse, mutect2
- LINC02693 | n.3893_3896del | RNA (DEL) | VAF 56/176 reads (32%) | called by mutect2, pindel, varscan2
- MACF1 | c.15832-11329G>A | Intron (SNP) | VAF 36/135 reads (27%) | catalogued as rs778128549; called by muse, mutect2, varscan2
- MUC19 | n.17641C>G | RNA (SNP) | VAF 142/465 reads (31%) | called by muse, mutect2, varscan2
- NBPF9 | c.-20C>T | 5'UTR (SNP) | VAF 85/346 reads (25%) | called by muse, mutect2, varscan2
- NRXN3 | c.*7G>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- NUP155 | c.*8G>A | 3'UTR (SNP) | VAF 43/205 reads (21%) | called by muse, mutect2, varscan2
- RNU1-1 | chr1:16514782 G>C | 5'Flank (SNP) | VAF 32/118 reads (27%) | catalogued as rs1244747883; called by muse, varscan2
- SACS | c.*728C>T | 3'UTR (SNP) | VAF 19/67 reads (28%) | catalogued as rs1397295387; called by muse, mutect2, varscan2
- TEPSIN | c.48+391C>T | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- TPM2 | c.563+197G>A | Intron (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- ZNF484 | c.-31+49G>A | Intron (SNP) | VAF 40/195 reads (21%) | catalogued as rs1161815309; called by muse, mutect2, varscan2
